Somatic mutation profile of tumor specimen TCGA-AB-2956-03A (aliquot TCGA-AB-2956-03A-01W-0733-08) from TCGA case TCGA-AB-2956, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.7 years (22,523 days).
Specimen TCGA-AB-2956-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd5fc6de-ec2d-4962-8473-dbb4089696df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2956-11A (Solid Tissue Normal), aliquot TCGA-AB-2956-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fff4db96-cded-4336-9647-e31d6d3a2b33

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Nonsense Mutation 2, Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNA2 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 20/228 reads (9%) | catalogued as COSV100559522, COSV58169832; called by muse, mutect2
- LPIN2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1270217201, COSV55242037; called by muse, mutect2
- PKP2 | c.439A>T p.R147* | Nonsense Mutation (SNP) | VAF 50/762 reads (7%) | catalogued as COSV99297241; called by muse, mutect2
- POLR2B | c.2128A>G p.I710V | Missense Mutation (SNP) | VAF 46/890 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs1000276015, COSV100107837; called by muse, mutect2
- GRM6 | c.678C>A p.G226= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99179457; called by mutect2, varscan2
- RWDD4 | c.33A>G p.L11= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100419072; called by muse, mutect2
